Surgical pathology report (de-identified scan), TCGA case TCGA-NA-A4QY, project TCGA-UCS (Uterine Carcinosarcoma), tissue source site Duke University, specimen TCGA-NA-A4QY-01A (Primary Tumor).

[page 1 of 3]
Surg Path

CLINICAL HISTORY:

Malignant neoplasm corpus uteri-182.0 (illegible) = carcinosarcoma.

GROSS EXAMINATION:

A. "Right periaortic", received fresh and placed in formalin on [redacted] at [redacted] is a 4 x 2.5 x 1 cm aggregate of fibroadipose tissue. Seven lymph node candidates are identified ranging from 0.4 x 0.4 x 0.2 cm up to 1.2 x 1 x 0.5 cm. The largest lymph node candidate is bisected and exhibits a white-brown firm cut surface.

BLOCK SUMMARY:

- A1- six intact lymph node candidates
- A2- one bisected lymph node candidate
- A3- the remainder of the fibrofatty tissue

ICD-0-3
Carcinosarcoma (malignant mesodermal
mixed tumor) 8951/3
Site: Uterus, NOS CSS.4
Copted AUS 1/6/13

B. "Left periaortic node", received fresh and placed in formalin on [redacted] at [redacted] is a 2.5 x 2.5 x 1 cm aggregate of fibrous adipose tissue. Three lymph node candidates are identified ranging from 0.6 x 0.5 x 0.3 cm up to 1.5 x 1.3 x 0.6 cm. The two lymph node candidates are bisected (one inked blue), the inked lymph node exhibits a brown, red, soft cut surface, while the non-inked lymph node candidate exhibits a tan-yellow, soft cut surface.

BLOCK SUMMARY:

- B1- one intact and one bisected (inked blue) lymph node candidate
- B2- one bisected lymph node candidate
- B3- remainder of the fibrofatty tissue

C. "Anterior peritoneal node", received fresh and placed in formalin on [redacted] at [redacted] is a 1.5 x 1.1 x 0.7 cm tan-pink, rubbery nodule. Sectioning exhibits a white, pink, smooth, whorled, soft cut surface. The nodule is submitted entirely in block C1.

D. "Right external iliac lymph node", received fresh and placed in formalin on [redacted] at [redacted] is a 4 x 2.3 x 0.7 cm aggregate of fibrous adipose tissue. One lymph node candidate (0.7 x 0.3 x 0.2 cm) is identified and submitted intact in block D1. The remainder of the adipose tissue is submitted entirely in blocks D2-3.

E. "Right obturator", received fresh and placed in formalin on [redacted] at [redacted] is a 5 x 3 x 2 cm aggregate of fibrous adipose tissue. Six lymph node candidates are identified ranging from 0.2 x 0.2 x 0.1 cm up to 4.5 x 1.8 x 0.8 cm. The largest lymph node candidates is sectioned and exhibits a red-brown, smooth, soft cut surface. The mid-sized lymph node (inked blue) is bisected and exhibits a tan-pink, soft, smooth cut surface.

BLOCK SUMMARY:

- E1- four intact lymph node candidates
- E2- one bisected lymph node candidate (inked blue)
- E3-5- the largest lymph node candidate
- E6-7- the remainder of the fibrofatty tissue

F. "Left pelvic lymph node", received fresh and placed in formalin on [redacted] at [redacted] is a 3.5 x 2 x 1.5 cm aggregate of fibrous adipose tissue. Two lymph node candidates ranging from 1.5 x 0.8 x 0.5 cm (inked blue) up to 1.7 x 1 x 0.6 cm are identified and bisected revealing a pink-red, soft, smooth cut

[page 2 of 3]
surface.

BLOCK SUMMARY:

- F1- largest lymph node bisected
- F2- lymph node candidate, bisected (inked blue)
- F3-4- remainder of fibrous adipose tissue

G. "Uterus, bilateral tubes and ovaries", received fresh and placed in formalin on [REDACTED] is a 335 gram, 14 x 13 x 7.5 cm disrupted fragmented uterus with attached right ovary (3 x 1 x 0.3 cm), fimbriated fallopian tube (6 x 0.6 cm), detached left ovary (3 x 1.2 x 0.4 cm), detached non-fimbriated left fallopian tube (4.5 x 0.3 cm), and detached cervix (3 cm with a 0.5 cm os).

The largest fragment is supracervical consistent with body and fundus of the uterus, and has a smooth, pink-tan endometrium (0.1 cm) with tattered edges. Within the endometrial cavity is a 3.5 x 1.5 x 2.1 cm (protruding into cavity) pink-tan, rubbery, exophytic mass.

On cut surface, the mass is grossly confined to the endometrium and overlies a 3.9 cm thick myometrium. Based on the attached right adnexa, the mass appears to be positioned on the anterior endometrium. The myometrium has roughly 17 intramural, homogenous, white, whorled nodules ranging from 0.7 x 0.6 x 0.5 cm up to 5 x 4.5 x 3.5 cm.

The uterine serosa is smooth with focal adhesions and a 0.5 x 0.3 x 0.3 cm, homogenous, white, whorled serosal nodule. The left and right fallopian tubes and ovaries are grossly unremarkable. The ectocervix has a pink-tan, smooth, grossly unremarkable endocervical canal.

Within the aggregate is a 6.5 x 5 x 2.5 cm aggregate of mass, myometrium (6 x 6 x 3 cm aggregate), and three leiomyomata ranging from 2 x 1.5 x 1 cm up to 4 x 3 x 3 cm.

BLOCK SUMMARY:

- G1-3- anterior mass, full-thickness (trisected)
- G4-6- additional sections of mass
- G7-9- intramural nodules
- G10- subserosal nodule
- G11- anterior cervix
- G12- anterior perpendicular lower uterine segment extending into endocervical canal
- G13- posterior cervix
- G14- posterior perpendicular intrauterine segment extending into endocervical canal
- G15- left fallopian tube and ovary
- G16- right fallopian tube and ovary
- G17- representative of mass aggregate
- G18- representative of the three leiomyomata

H. "Appendix", received fresh and placed in formalin on [REDACTED] is a 5 cm long x 0.6 cm diameter vermiform appendix with 2 cm of attached mesoappendix. The serosal surface is smooth, tan-pink, and intact. The specimen has a uniform wall thickness of 0.2 cm diameter which contains fecal material towards the distal end. The distal tip mucosa is tan-pink and focally hemorrhagic.

BLOCK SUMMARY:

- H1- representative cross sections (margin inked blue)
- H2- longitudinal section of distal tip
- [REDACTED]

MICROSCOPIC EXAMINATION:

[REDACTED]

[page 3 of 3]
Microscopic examination is performed.

DIAGNOSIS:

A. RIGHT PERIAORTIC LYMPH NODES (DISSECTION):

NO TUMOR SEEN IN EIGHT LYMPH NODES .

B. LEFT PERIAORTIC LYMPH NODES (DISSECTION):

NO TUMOR SEEN IN THREE LYMPH NODES.

C. ANTERIOR PERITONEAL LYMPH NODE (EXCISION):

NODULAR FOCUS OF CARCINOSARCOMA, 1.5 CM.
NO LYMPH NODE ARCHITECTURE IS SEEN.

Comment: No lymph node architecture is seen in specimen C. This may represent an extranodal tumor deposit, a lymph node entirely replaced by tumor, or fragmentation of the main tumor. Clinical correlation is needed.

D. RIGHT EXTERNAL ILIAC LYMPH NODE (EXCISION):

NO TUMOR SEEN IN TWO LYMPH NODES.

E. RIGHT OBTURATOR LYMPH NODES (DISSECTION):

NO TUMOR SEEN IN SIX LYMPH NODES.

F. LEFT PELVIC LYMPH NODES (DISSECTION):

NO TUMOR SEEN IN TWO LYMPH NODES.

G. UTERUS WITH BILATERAL OVARIES AND FALLOPIAN TUBES (HYSTERECTOMY):

UTERUS: 335 GRAMS

ENDOMETRIUM:

TUMOR SITE: THE SPECIMEN IS RECEIVED FRAGMENTED. TUMOR APPEARS TO BE PRESENT ON THE ANTERIOR UTERINE WALL AND IN A SEPARATE DETACHED FRAGMENT.

HISTOLOGIC TYPE: CARCINOSARCOMA (MALIGNANT MESODERMAL MIXED TUMOR).

FIGO GRADE: 3.

TUMOR SIZE: THE TUMOR MEASURES 3.5 CM IN GREATEST DIMENSION WITHIN THE UTERINE BODY. THERE IS AN ADDITIONAL SEPARATE AGGREGATE OF TUMOR MEASURING 6.5 X 5 X 2.5 CM. .

MAXIMUM DEPTH OF MYOMETRIAL INVASION: 0.4 CM, IN A 2.1CM THICK WALL (19 %).

LYMPHATIC/VASCULAR INVASION: ABSENT

ADJACENT NON-NEOPLASTIC ENDOMETRIUM: UNREMARKABLE.

REMAINING MYOMETRIUM: MULTIPLE LEIOMYOMAS MEASURING UP TO 5 CM.

CERVIX: NO PATHOLOGIC ABNORMALITY.

SEROSA: SEROSAL ADHESIONS. NEGATIVE FOR CARCINOMA.

H. APPENDIX (APPENDECTOMY):

NO PATHOLOGIC ABNORMALITY.

NO EVIDENCE OF ACUTE APPENDICITIS OR NEOPLASM.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Source: NCI Genomic Data Commons file 3fc26cdf-ede7-4950-9b2b-007d2b199f60 (TCGA-NA-A4QY.8C27661B-E1AD-4436-AD4D-D9DAEF99362D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).